Somatic mutation profile of tumor specimen C3L-05481-03 (aliquot CPT0406370007) from CPTAC case C3L-05481, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 53.4 years (19,500 days).
Specimen C3L-05481-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c4164e2c-361f-4e86-9be8-2520b7f66eed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05481-31 (Blood Derived Normal), aliquot CPT0402530002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bbccd1fa-a18e-445d-993e-e4c12bdc9f89

The open-access MAF lists 65 somatic variants for this specimen: 37 protein-altering or splice-affecting, 20 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 20, 3'UTR 4, Frame Shift Ins 3, RNA 2, Intron 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EHHADH | c.305G>T p.G102V | Missense Mutation (SNP) | VAF 56/134 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs147693859; called by muse, mutect2, varscan2
- FAM124B | c.253G>A p.V85I | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as rs756001279, COSV54739186; called by muse, mutect2, varscan2
- HFM1 | c.4163dup p.N1388Kfs*8 | Frame Shift Ins (INS) | VAF 18/38 reads (47%) | catalogued as rs759278255, COSV99646600; called by mutect2, varscan2
- HS6ST3 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.838); catalogued as rs368419692; called by muse, mutect2, varscan2
- IGF2BP1 | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 59/132 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); catalogued as rs368043361; called by muse, mutect2, varscan2
- KIF24 | c.3847C>T p.R1283C | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs145943303; called by muse, mutect2, varscan2
- LRRC32 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 168/434 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs143012117; called by muse, mutect2
- LRRIQ4 | c.917G>A p.R306H | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.12); catalogued as rs1350298585; called by muse, mutect2, varscan2
- PLXNA3 | c.4777C>T p.R1593C | Missense Mutation (SNP) | VAF 85/242 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs192776944, COSV100860318, COSV63753749; called by muse, mutect2, varscan2
- PRR23A | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.39); catalogued as rs765076882, COSV67214626, COSV67214848; called by muse, mutect2, varscan2
- PTEN | c.506C>A p.P169H | Missense Mutation (SNP) | VAF 74/116 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64289432, COSV64310666; called by muse, mutect2, varscan2
- SYNJ2 | c.3689G>A p.R1230Q | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs544005647, COSV62896616; called by muse, mutect2, varscan2
- TMEM200A | c.515C>T p.T172M | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.65); catalogued as rs149308469, COSV51656363; called by muse, mutect2, varscan2
- USP17L10 | c.1186G>A p.V396I | Missense Mutation (SNP) | VAF 328/540 reads (61%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs1273439998; called by muse, varscan2
- VNN3 | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774659578; called by muse, mutect2, varscan2
- ABCA13 | c.10354C>A p.L3452I | Missense Mutation (SNP) | VAF 81/249 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRF2 | c.1858A>T p.I620F (on ENST00000296862 / NM_001368115.2; = p.I552F on NM_153839.7) | Missense Mutation (SNP) | VAF 93/221 reads (42%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- AHNAK | c.86A>C p.D29A | Missense Mutation (SNP) | VAF 61/179 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ALS2CL | c.1528T>A p.F510I | Missense Mutation (SNP) | VAF 81/191 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BTD | c.811G>T p.A271S | Missense Mutation (SNP) | VAF 122/312 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- DSC2 | c.593C>A p.T198N | Missense Mutation (SNP) | VAF 80/255 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- EPHB6 | c.2546G>T p.G849V | Missense Mutation (SNP) | VAF 149/690 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FNDC1 | c.1903dup p.L635Pfs*7 | Frame Shift Ins (INS) | VAF 20/62 reads (32%) | called by mutect2, pindel, varscan2
- LZTS3 | c.1608C>A p.C536* (on ENST00000329152; = p.C490* on NM_001282533.2) | Nonsense Mutation (SNP) | VAF 181/440 reads (41%) | called by muse, mutect2, varscan2
- MINDY4 | c.304A>G p.K102E | Missense Mutation (SNP) | VAF 129/458 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- OR2J1 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 71/156 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PNISR | c.1397dup p.L466Ffs*12 | Frame Shift Ins (INS) | VAF 27/87 reads (31%) | called by mutect2, pindel, varscan2
- PWWP2A | c.2186G>A p.R729H | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- RNF34 | c.17C>T p.T6M | Missense Mutation (SNP) | VAF 64/158 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.891); called by muse, mutect2
- SPATA31E1 | c.1745C>T p.P582L | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.78); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- SS18 | c.1069G>C p.G357R (on ENST00000415083 / NM_001007559.3; = p.G326R on NM_005637.3) | Missense Mutation (SNP) | VAF 84/212 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- TFIP11 | c.1617G>T p.W539C | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TLL1 | c.1880G>T p.G627V | Missense Mutation (SNP) | VAF 110/333 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM266 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- TOGARAM1 | c.1547C>A p.A516D | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TTLL13P | c.1508C>A p.A503D | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.198); called by muse, mutect2
- ZC3H6 | c.1078T>G p.L360V | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ABLIM3 | c.1014C>T p.D338= | Silent (SNP) | VAF 70/178 reads (39%) | catalogued as rs144195918; called by muse, mutect2, varscan2
- ANK1 | c.3012C>T p.R1004= | Silent (SNP) | VAF 125/350 reads (36%) | catalogued as rs142610966; called by muse, mutect2, varscan2
- CD33 | c.204C>T p.S68= | Silent (SNP) | VAF 51/165 reads (31%) | catalogued as COSV99220064; called by muse, mutect2, varscan2
- CFH | c.3531T>C p.Y1177= | Silent (SNP) | VAF 126/318 reads (40%) | catalogued as rs1438529897; called by muse, mutect2, varscan2
- DLK1 | c.819C>T p.H273= | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as rs766810694, COSV57993254; called by muse, mutect2, varscan2
- DSC2 | c.594T>C p.T198= | Silent (SNP) | VAF 79/250 reads (32%) | called by muse, mutect2, varscan2
- FCGBP | c.10488C>T p.D3496= | Silent (SNP) | VAF 212/535 reads (40%) | catalogued as rs771508776; called by muse, mutect2, varscan2
- FERMT2 | c.2010G>A p.E670= | Silent (SNP) | VAF 42/114 reads (37%) | called by muse, mutect2, varscan2
- GJB1 | c.270C>T p.L90= | Silent (SNP) | VAF 30/82 reads (37%) | catalogued as rs938061009; ClinVar: likely benign; called by muse, mutect2, varscan2
- LOXHD1 | c.2751G>A p.K917= | Silent (SNP) | VAF 197/529 reads (37%) | catalogued as rs940679061; called by muse, mutect2, varscan2
- MAP1S | c.2028G>A p.T676= | Silent (SNP) | VAF 41/124 reads (33%) | catalogued as rs1257739056; called by muse, mutect2, varscan2
- MARCHF9 | c.969G>A p.Q323= | Silent (SNP) | VAF 54/119 reads (45%) | called by muse, mutect2, varscan2
- NDNF | c.1083G>A p.K361= | Silent (SNP) | VAF 47/126 reads (37%) | catalogued as rs772059769; called by muse, mutect2, varscan2
- NPVF | c.372T>C p.V124= | Silent (SNP) | VAF 72/255 reads (28%) | called by muse, mutect2, varscan2
- OR11L1 | c.546G>A p.P182= | Silent (SNP) | VAF 113/298 reads (38%) | catalogued as rs777477000, COSV63314143; called by muse, mutect2
- PRKCA | c.678C>G p.S226= | Silent (SNP) | VAF 19/57 reads (33%) | called by muse, mutect2, varscan2
- SIGLEC7 | c.798C>A p.V266= | Silent (SNP) | VAF 7/176 reads (4%) | called by muse, mutect2
- SYP | c.753C>T p.G251= | Silent (SNP) | VAF 79/212 reads (37%) | called by muse, mutect2, varscan2
- TAGAP | c.1416G>A p.S472= | Silent (SNP) | VAF 53/154 reads (34%) | catalogued as rs544687859; called by muse, mutect2, varscan2
- TENM1 | c.2007C>T p.H669= | Silent (SNP) | VAF 137/359 reads (38%) | catalogued as rs768785681, COSV100949008; called by muse, mutect2, varscan2
- BEGAIN | c.-15-13T>G | Intron (SNP) | VAF 83/232 reads (36%) | called by muse, mutect2, varscan2
- CEP170P1 | n.3627G>A | RNA (SNP) | VAF 63/238 reads (26%) | called by muse, mutect2, varscan2
- CXCL5 | c.*17C>T | 3'UTR (SNP) | VAF 22/63 reads (35%) | catalogued as rs199526761, COSV56018287; called by muse, mutect2, varscan2
- HERC2P3 | n.1377+11G>A | Intron (SNP) | VAF 96/208 reads (46%) | catalogued as rs762090465; called by muse, mutect2, varscan2
- OR3A4P | n.1013C>T | RNA (SNP) | VAF 97/221 reads (44%) | catalogued as rs766148919; called by muse, mutect2, varscan2
- SHROOM4 | c.*514G>C | 3'UTR (SNP) | VAF 120/311 reads (39%) | called by muse, mutect2, varscan2
- SHROOM4 | c.*121C>A | 3'UTR (SNP) | VAF 183/438 reads (42%) | called by muse, mutect2, varscan2
- UQCRB | c.*2085C>G | 3'UTR (SNP) | VAF 103/289 reads (36%) | catalogued as rs1210161721; called by muse, mutect2, varscan2
